Somatic mutation profile of tumor specimen TCGA-AB-2854-03B (aliquot TCGA-AB-2854-03B-01W-0728-08) from TCGA case TCGA-AB-2854, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.5 years (18,809 days).
Specimen TCGA-AB-2854-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0a31c6a-9a96-4e68-8894-c07d94954556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2854-11B (Solid Tissue Normal), aliquot TCGA-AB-2854-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20277997-1c1a-45d5-b302-09252f38acc7

The open-access MAF lists 285 somatic variants for this specimen: 202 protein-altering or splice-affecting, 79 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 79, Frame Shift Ins 13, Nonsense Mutation 13, Splice Site 5, 3'UTR 2, Frame Shift Del 2, Splice Region 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC16A1 | c.41dup p.D15Rfs*34 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- AC092143.1 | c.1999C>A p.R667S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV59247493, COSV59247824; called by muse, mutect2, varscan2
- ACSM1 | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 82/1776 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532979; called by muse, mutect2
- ADAM11 | c.2150C>A p.T717K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.115); catalogued as COSV52346234; called by muse, mutect2, varscan2
- ADAM12 | c.1727+1G>A p.X576_splice | Splice Site (SNP) | VAF 20/480 reads (4%) | catalogued as COSV100900562; called by muse, mutect2
- ADAR | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 36/379 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1225707553, COSV52715168; called by muse, mutect2
- ADGRG3 | c.1118C>A p.T373N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59651081; called by muse, mutect2, varscan2
- AFF1 | c.339C>G p.H113Q | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1415928247, COSV100320607; called by muse, mutect2
- AL441992.2 | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56913670; called by muse, mutect2
- ALOXE3 | c.1873T>C p.Y625H | Missense Mutation (SNP) | VAF 16/333 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100559703; called by muse, mutect2
- AMOTL1 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100133791; called by muse, mutect2
- AMOTL2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs372900931; called by muse, mutect2, varscan2
- ANKRD34A | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100041256; called by muse, mutect2
- ANKS1A | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 12/361 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100832447; called by muse, mutect2
- ARHGAP24 | c.1306G>A p.G436R (on ENST00000395184 / NM_001025616.3; = p.G343R on NM_031305.3) | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs754756194, COSV51988840; called by muse, mutect2, varscan2
- ASXL1 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100039299, COSV100041028; called by muse, mutect2
- ATIC | c.543T>A p.H181Q | Missense Mutation (SNP) | VAF 20/816 reads (2%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV99377796; called by muse, mutect2
- ATP8B3 | c.2009T>A p.L670* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV59542644; called by muse, mutect2, varscan2
- ATP9A | c.923T>C p.F308S | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100124979; called by muse, mutect2
- AZIN1 | c.74T>C p.I25T | Missense Mutation (SNP) | VAF 28/747 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV100457556; called by muse, mutect2
- BDH1 | c.700A>T p.S234C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs1461933313, COSV100827135; called by muse, mutect2
- BEST3 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199594674; called by muse, mutect2, varscan2
- BIRC6 | c.9535G>A p.A3179T | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101428303; called by muse, mutect2
- BNIP5 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 20/309 reads (6%) | catalogued as rs1370294099, COSV101465148; called by muse, mutect2
- BUB3 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 154/581 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64363488; called by muse, mutect2, varscan2
- C3 | c.4699C>T p.Q1567* | Nonsense Mutation (SNP) | VAF 62/1052 reads (6%) | catalogued as COSV99836661; called by muse, mutect2
- C5orf24 | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV100574506; called by muse, mutect2
- CASP3 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV57725074; called by muse, mutect2, varscan2
- CCDC150 | c.478T>A p.L160M | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99776929; called by muse, mutect2
- CCDC66 | c.965G>A p.S322N (on ENST00000394672 / NM_001353147.1; = p.S288N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100413991; called by muse, mutect2
- CCDC77 | c.1065A>T p.Q355H | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99519865; called by muse, mutect2
- CD34 | c.785dup p.H263Afs*4 | Frame Shift Ins (INS) | VAF 69/336 reads (21%) | catalogued as rs1248260538; called by mutect2, pindel, varscan2
- CES2 | c.452T>A p.L151H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57696846, COSV57697217; called by muse, varscan2
- CHD6 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 48/1909 reads (3%) | catalogued as COSV100498291; called by muse, mutect2
- CHL1 | c.1040A>T p.N347I (on ENST00000397491 / NM_001253387.1; = p.N363I on NM_006614.4) | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV99851243; called by muse, mutect2
- CKAP4 | c.1677T>A p.S559R | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100952456; called by muse, mutect2
- CNTNAP1 | c.2030G>A p.C677Y | Missense Mutation (SNP) | VAF 24/461 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99226434; called by muse, mutect2
- COL2A1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100476490; called by muse, mutect2
- CYBB | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as COSV66085361; called by muse, mutect2, varscan2
- CYP2A13 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV100386823; called by muse, mutect2
- CYP4F11 | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56126956; called by muse, mutect2, varscan2
- DHX38 | c.395G>C p.S132T | Missense Mutation (SNP) | VAF 30/868 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV99194323; called by muse, mutect2
- DNAH10 | c.7851G>T p.E2617D (on ENST00000409039; = p.E2556D on NM_207437.3) | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.101); catalogued as COSV68993570; called by muse, mutect2, varscan2
- DSCAML1 | c.3956A>G p.Q1319R (on ENST00000321322; = p.Q1259R on NM_020693.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV58390314; called by muse, mutect2, varscan2
- DYNC1LI1 | c.725T>A p.V242E | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99818159; called by muse, mutect2
- EFCAB11 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99965648; called by muse, mutect2
- EFS | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99391560; called by muse, mutect2, varscan2
- EPB42 | c.1472C>T p.A491V (on ENST00000441366 / NM_001114134.2; = p.A521V on NM_000119.3) | Missense Mutation (SNP) | VAF 41/582 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100281976; called by muse, mutect2
- EVPL | c.5635G>C p.V1879L | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100044547; called by muse, mutect2
- FAM160B1 | c.1304T>A p.L435H | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100985438; called by muse, mutect2
- FAM166A | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV61116596; called by muse, mutect2, varscan2
- FBXO40 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV100573176; called by muse, mutect2
- FLOT1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV99458198; called by muse, mutect2
- FRG2 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.862); catalogued as COSV66459955; called by muse, mutect2
- FRYL | c.3170-1G>A p.X1057_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV51946721; called by muse, mutect2, varscan2
- G6PD | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV63703044, COSV63703367; called by muse, mutect2, varscan2
- GAPDHS | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as rs1461856740, COSV99722794; called by muse, mutect2
- GOLGA1 | c.2227T>C p.S743P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52346776; called by mutect2, varscan2
- GPATCH2 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs991212267, COSV100861346, COSV100861352, COSV100861383; called by muse, mutect2
- GRIK5 | c.1028G>C p.G343A | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53478456; called by muse, mutect2, varscan2
- HCK | c.1178T>A p.L393Q | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99394073; called by muse, mutect2
- HEY1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100559233; called by muse, mutect2
- IFT140 | c.3484C>T p.Q1162* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV63697893; called by muse, mutect2, varscan2
- IFT172 | c.4054G>A p.A1352T | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1418646322, COSV99562515; called by muse, mutect2
- IL17RE | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777074215, COSV55968189; called by muse, mutect2, varscan2
- INPP4A | c.2780A>G p.Q927R (on ENST00000074304 / NM_001134224.1; = p.Q888R on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV99303907; called by muse, mutect2
- INSR | c.3164C>T p.A1055V | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM000407, COSV57158745; called by muse, mutect2
- IQSEC2 | c.3206G>A p.R1069Q (on ENST00000642864 / NM_001111125.3; = p.R864Q on NM_015075.2) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs782632137, COSV64725358; called by muse, mutect2, varscan2
- ITGA10 | c.2207G>A p.C736Y | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100994908; called by muse, mutect2
- ITIH4 | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99819410; called by muse, mutect2
- IZUMO1R | c.616C>T p.P206S (on ENST00000440961; = p.P213S on NM_001199206.3) | Missense Mutation (SNP) | VAF 26/604 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.664); catalogued as rs1295027944, COSV60623254; called by muse, mutect2
- KANSL3 | c.1954T>C p.S652P (on ENST00000666923 / NM_001349262.2; = p.S626P on NM_001115016.3) | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV100831123; called by muse, mutect2
- KCNC1 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.019); catalogued as COSV56394162; called by muse, varscan2
- KCNS2 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.331); catalogued as rs765435145, COSV54638503; called by muse, mutect2, varscan2
- KCNV1 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52087108; called by muse, mutect2
- KDM4D | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782273063, COSV100624267; called by muse, mutect2
- KDM7A | c.1703C>G p.P568R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV99134475; called by muse, mutect2
- KIAA0319 | c.667T>A p.S223T | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV100985568; called by muse, mutect2
- KIAA0319 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100985572; called by muse, mutect2
- LARS1 | c.2587T>C p.C863R (on ENST00000394434 / NM_020117.11; = p.C836R on NM_016460.3) | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99198608; called by muse, mutect2
- LCOR | c.2960T>C p.V987A | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99616893; called by muse, mutect2
- LDLRAD4 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV63337222; called by muse, mutect2
- LIMA1 | c.1957T>C p.W653R | Missense Mutation (SNP) | VAF 28/1000 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100372447; called by muse, mutect2
- LINGO2 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1438339437, COSV58059635; called by muse, mutect2
- LNX1 | c.1436G>T p.S479I (on ENST00000263925 / NM_001126328.3; = p.S383I on NM_032622.2) | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as COSV99820002; called by muse, mutect2
- LRIT2 | c.1363G>T p.G455C | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100258882; called by muse, mutect2
- LRRC3B | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV101185884; called by muse, mutect2
- MAMLD1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53374669; called by muse, mutect2, varscan2
- MAN1B1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1356921253, COSV64306538; called by muse, mutect2, varscan2
- MAN2B1 | c.215A>C p.H72P | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906261, CM970909, COSV54418282; called by muse, mutect2, varscan2
- MCCC2 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 8/148 reads (5%) | catalogued as COSV100040168; called by muse, mutect2
- MED6 | c.252A>T p.Q84H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99833002; called by muse, mutect2
- MEFV | c.1288C>A p.L430M | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99560878; called by muse, mutect2
- MGLL | c.106A>G p.K36E (on ENST00000398104 / NM_001003794.2; = p.K46E on NM_007283.6) | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99411868; called by muse, mutect2
- MNS1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1428933655, COSV53068250; called by muse, mutect2
- MOG | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs200307543, COSV100973015; called by muse, mutect2
- MROH2B | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs779723416, COSV101270936, COSV68183908; called by muse, varscan2
- MRPL11 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs934890635, COSV100207771; called by muse, mutect2
- MRTO4 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 21/502 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs1558122326, COSV100367474; called by muse, mutect2
- MSS51 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1564541064, COSV100200163; called by muse, mutect2
- MUC13 | c.590G>C p.C197S | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100222343; called by muse, mutect2
- MYC | c.58C>T p.Q20* (on ENST00000377970; = p.Q35* on NM_002467.6) | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as COSV99420415; called by muse, mutect2
- NFATC4 | c.2680G>T p.A894S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV51602251; called by muse, mutect2, varscan2
- NFE2L1 | c.1966C>T p.R656* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100671390, COSV100671574; called by muse, mutect2
- NR6A1 | c.597-2A>G p.X199_splice | Splice Site (SNP) | VAF 16/208 reads (8%) | catalogued as COSV100748556; called by muse, mutect2
- NRXN2 | c.2749G>T p.A917S | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV99634248; called by muse, mutect2
- OR6B1 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV68770312; called by muse, mutect2
- OTUD7B | c.1867T>C p.Y623H | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV100967554; called by muse, mutect2
- PAH | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100188074; called by muse, mutect2
- PAPPA2 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs771937888, COSV62796581; called by muse, mutect2, varscan2
- PCDHB16 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV53362100; called by muse, mutect2, varscan2
- PCDHGA11 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV54043945; called by muse, mutect2
- PCNX2 | c.2582G>A p.S861N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1187440408, COSV99267699; called by muse, mutect2
- PEX19 | c.834T>A p.F278L | Missense Mutation (SNP) | VAF 28/582 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV100926952; called by muse, mutect2
- PJA1 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV64053125; called by muse, mutect2
- PKHD1 | c.4021C>T p.Q1341* | Nonsense Mutation (SNP) | VAF 13/142 reads (9%) | catalogued as rs1427552447, COSV61874764; called by muse, mutect2
- PKM | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs1186427079, COSV100064821, COSV99069963; called by muse, mutect2
- POLR1B | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.077); catalogued as COSV54497913; called by muse, mutect2
- PPARGC1B | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100494754; called by muse, mutect2
- PRAG1 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV58160787; called by muse, mutect2, varscan2
- PRKAG2 | c.1346T>C p.L449S | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99835348; called by muse, mutect2
- PROKR1 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.407); catalogued as COSV100375509; called by muse, mutect2
- PRRC2B | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61936925; called by muse, mutect2, varscan2
- PRUNE2 | c.5594C>T p.A1865V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100944576; called by muse, mutect2
- PRX | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 213/240 reads (89%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); catalogued as COSV52529866; called by muse, mutect2, varscan2
- PSME4 | c.4337T>G p.L1446R | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV66364874; called by muse, mutect2, varscan2
- PTCHD4 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV59783859; called by muse, mutect2
- PTK2B | c.2770G>T p.V924L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV57756228, COSV57765448; called by muse, mutect2, varscan2
- RALGPS1 | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52221773; called by muse, varscan2
- RASSF1 | c.460C>T p.L154F (on ENST00000357043 / NM_170714.2; = p.L150F on NM_007182.5) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs767866558, COSV51700580; called by muse, mutect2, varscan2
- RBMX2 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV59729205; called by muse, mutect2, varscan2
- RNF144B | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 27/832 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.052); catalogued as COSV99464639; called by muse, mutect2
- RNF38 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV52394470; called by muse, varscan2
- RPH3AL | c.352-2A>G p.X118_splice | Splice Site (SNP) | VAF 6/102 reads (6%) | catalogued as rs1032486708; called by muse, mutect2
- RRM2B | c.403T>C p.S135P | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV52566745; called by muse, mutect2
- RYR1 | c.9128T>C p.F3043S | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100615765; called by muse, mutect2
- RYR2 | c.3386G>A p.G1129D | Missense Mutation (SNP) | VAF 41/1206 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100767177, COSV100770288; called by muse, mutect2
- SAMD9 | c.3314G>A p.W1105* | Nonsense Mutation (SNP) | VAF 14/344 reads (4%) | catalogued as COSV101180258; called by muse, mutect2
- SETDB1 | c.3605A>T p.D1202V | Missense Mutation (SNP) | VAF 64/2732 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99644678; called by muse, mutect2
- SFI1 | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV101192097; called by muse, mutect2
- SGSM3 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99960442; called by muse, mutect2
- SH2D4B | c.877C>A p.P293T (on ENST00000646907; = p.P292T on NM_207372.2) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV57895702; called by muse, mutect2, varscan2
- SHC1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58316182; called by muse, mutect2, varscan2
- SIX4 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99382261; called by muse, mutect2
- SLC16A7 | c.318T>A p.S106R | Missense Mutation (SNP) | VAF 26/941 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99676521; called by muse, mutect2
- SLC22A11 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 57/98 reads (58%) | catalogued as COSV100102342; called by muse, mutect2
- SPATA16 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 27/1028 reads (3%) | catalogued as COSV100651266; called by muse, mutect2
- SPRY3 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 18/539 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV100249352; called by muse, mutect2
- STK36 | c.2149-2A>G p.X717_splice | Splice Site (SNP) | VAF 70/632 reads (11%) | catalogued as COSV55326476; called by muse, mutect2, varscan2
- SV2B | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57699694; called by muse, mutect2
- SZT2 | c.6691A>G p.R2231G (on ENST00000634258 / NM_001365999.1; = p.R2174G on NM_015284.4) | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100987283; called by muse, mutect2
- TACC2 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.201); catalogued as COSV100552373, COSV57778428; called by muse, mutect2
- TCHHL1 | c.1499A>G p.Q500R | Missense Mutation (SNP) | VAF 58/2498 reads (2%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100916536; called by muse, mutect2
- TEK | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101193423; called by muse, mutect2
- TEP1 | c.2449A>G p.R817G | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99402436; called by muse, mutect2
- TFAM | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs375752119; called by muse, varscan2
- TJP1 | c.3097A>G p.K1033E | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.045); catalogued as rs1175602370, COSV100632723; called by muse, mutect2
- TMEM217 | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 27/1094 reads (2%) | SIFT tolerated (0.24); PolyPhen benign (0.34); catalogued as COSV100362547; called by muse, mutect2
- TNFSF8 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.984); catalogued as COSV99801854; called by muse, mutect2
- TNRC6A | c.3931G>A p.A1311T | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100170022; called by muse, mutect2
- TNS2 | c.863G>C p.S288T (on ENST00000314250 / NM_170754.4; = p.S298T on NM_015319.2) | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100048120; called by muse, mutect2
- TOGARAM1 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs1158427904, COSV100753120, COSV61887767; called by muse, mutect2
- TRPV6 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs370170865, COSV63893232; called by muse, mutect2
- TSC22D4 | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55724103; called by muse, mutect2, varscan2
- TSPAN33 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 13/350 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV99179740; called by muse, mutect2
- TTN | c.672G>A p.K224= | Splice Region (SNP) | VAF 9/102 reads (9%) | catalogued as COSV60048902; called by muse, mutect2
- UFSP2 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs957254401, COSV52991552; called by muse, mutect2
- UMOD | c.996G>T p.R332S | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV100208372; called by muse, mutect2
- USP19 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59733368; called by muse, mutect2, varscan2
- USP32 | c.3689C>T p.A1230V | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.523); catalogued as COSV56271842; called by muse, mutect2
- USP43 | c.2036G>A p.G679D | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99556689; called by muse, mutect2
- VPS13D | c.11693G>A p.S3898N | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV50637734; called by muse, mutect2, varscan2
- WARS1 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 10/213 reads (5%) | catalogued as COSV100690180; called by muse, mutect2
- ZBTB44 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100777276; called by muse, mutect2
- ZC3H12A | c.1409G>A p.G470D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV66104113; called by muse, mutect2
- ZFAND1 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV99605427; called by muse, mutect2
- ZFP36L1 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100322691; called by muse, mutect2
- ZNF347 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV100498299; called by muse, mutect2
- ZNF423 | c.1808A>G p.H603R (on ENST00000563137 / NM_001379286.1; = p.H595R on NM_015069.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV99281727; called by muse, mutect2, varscan2
- ZNF423 | c.767A>T p.K256M (on ENST00000563137 / NM_001379286.1; = p.K248M on NM_015069.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99281729; called by muse, mutect2
- ZNF622 | c.797A>T p.K266M | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100433073; called by muse, mutect2
- ZSWIM4 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs199623743, COSV54321684; called by muse, mutect2, varscan2
- ALDH4A1 | c.1441dup p.A481Gfs*7 | Frame Shift Ins (INS) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- ATL3 | c.1097A>T p.N366I | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.094); called by muse, mutect2
- BRD4 | c.3402dup p.K1135Qfs*42 | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- BTNL8 | c.1382del p.P461Qfs*109 | Frame Shift Del (DEL) | VAF 45/401 reads (11%) | called by mutect2, pindel, varscan2
- CFAP65 | c.1173dup p.F392Lfs*4 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- EGR1 | c.1088_1089dup p.G364Qfs*169 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- FAT2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPATCH4 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 38/997 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- GSTM4 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 24/690 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- H6PD | c.1267dup p.L423Pfs*74 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 26/587 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.254); called by muse, mutect2
- KEAP1 | c.1430dup p.F478Lfs*2 | Frame Shift Ins (INS) | VAF 10/89 reads (11%) | called by mutect2, pindel
- METTL18 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2
- MRM3 | c.839dup p.D281* | Frame Shift Ins (INS) | VAF 15/122 reads (12%) | called by mutect2, pindel
- NLRC5 | c.2815dup p.T939Nfs*24 | Frame Shift Ins (INS) | VAF 70/501 reads (14%) | called by mutect2, pindel, varscan2
- OFD1 | c.2939dup p.M981Dfs*14 | Frame Shift Ins (INS) | VAF 34/243 reads (14%) | called by mutect2, varscan2
- SYNJ2 | c.1239dup p.L414Afs*8 | Frame Shift Ins (INS) | VAF 13/114 reads (11%) | called by mutect2, pindel, varscan2
- TRIP10 | c.1315dup p.D439Gfs*11 (on ENST00000313244 / NM_001288962.2; = p.D383Gfs*11 on NM_004240.4) | Frame Shift Ins (INS) | VAF 16/113 reads (14%) | called by mutect2, pindel, varscan2
- TSHZ1 | c.3082del p.A1028Pfs*41 (on ENST00000580243 / NM_001308210.2; = p.A983Pfs*41 on NM_005786.6) | Frame Shift Del (DEL) | VAF 11/120 reads (9%) | called by mutect2, pindel
- WIZ | c.5594A>G p.N1865S (on ENST00000673675 / NM_001371589.1; = p.N770S on NM_021241.3) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- AAMP | c.360G>A p.R120= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV50307640; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1620C>T p.R540= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV99587612; called by muse, mutect2
- ADCY3 | c.1851C>T p.D617= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV53167422; called by muse, mutect2, varscan2
- ADRA1A | c.1206C>T p.S402= | Silent (SNP) | VAF 91/379 reads (24%) | catalogued as COSV52363566; called by muse, mutect2, varscan2
- AHSG | c.222C>T p.S74= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV99890031; called by muse, mutect2
- ANO5 | c.1725A>G p.V575= | Silent (SNP) | VAF 10/330 reads (3%) | catalogued as COSV61081718; called by muse, mutect2
- APOB | c.3183C>T p.S1061= | Silent (SNP) | VAF 14/546 reads (3%) | called by muse, mutect2
- APP | c.1788T>A p.S596= | Silent (SNP) | VAF 7/144 reads (5%) | catalogued as COSV100695768; called by muse, mutect2
- ARFGEF2 | c.1201C>T p.L401= | Silent (SNP) | VAF 9/215 reads (4%) | catalogued as COSV100904262; called by muse, mutect2
- ARHGEF10L | c.624G>A p.L208= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100769835; called by muse, mutect2
- BPI | c.1333C>T p.L445= (on ENST00000262865; = p.L441= on NM_001725.3) | Silent (SNP) | VAF 92/1698 reads (5%) | catalogued as COSV99480645; called by muse, mutect2
- CABP4 | c.732G>A p.A244= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as rs566372218, COSV57798043; called by muse, mutect2
- CALML5 | c.153A>G p.K51= | Silent (SNP) | VAF 14/263 reads (5%) | catalogued as COSV100981199; called by muse, mutect2
- CCDC97 | c.90G>A p.R30= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs766123036, COSV54190289; called by muse, mutect2, varscan2
- CCL21 | c.220C>T p.L74= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV52398638; called by muse, mutect2
- CDAN1 | c.1437G>A p.K479= | Silent (SNP) | VAF 6/180 reads (3%) | catalogued as rs1334619694, COSV100661316; called by muse, mutect2
- CDX2 | c.807G>A p.Q269= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV101122678; called by muse, mutect2
- CHL1 | c.2169T>C p.S723= (on ENST00000397491 / NM_001253387.1; = p.S739= on NM_006614.4) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV56593144; called by muse, mutect2, varscan2
- CLK1 | c.183T>A p.S61= | Silent (SNP) | VAF 9/205 reads (4%) | catalogued as COSV58434626; called by muse, mutect2
- CTDSP2 | c.744G>A p.L248= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV66079916; called by muse, mutect2, varscan2
- DARS2 | c.1350T>A p.S450= | Silent (SNP) | VAF 28/393 reads (7%) | catalogued as COSV99508721; called by muse, mutect2
- DHRS11 | c.531A>G p.T177= | Silent (SNP) | VAF 7/172 reads (4%) | called by muse, mutect2
- DHX58 | c.2014T>C p.L672= | Silent (SNP) | VAF 33/222 reads (15%) | catalogued as COSV52425842; called by muse, mutect2, varscan2
- DLX3 | c.597C>T p.P199= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV101460559; called by muse, mutect2
- DSN1 | c.279G>A p.R93= | Silent (SNP) | VAF 40/902 reads (4%) | catalogued as COSV101041037; called by muse, mutect2
- DUOX2 | c.1263C>T p.S421= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV66532067; called by muse, mutect2, varscan2
- ELF5 | c.345C>T p.G115= (on ENST00000312319 / NM_198381.2; = p.G105= on NM_001422.4) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs200848772, COSV56628896; called by muse, mutect2, varscan2
- FAM83C | c.1164C>T p.A388= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100981571; called by muse, mutect2
- FAT2 | c.3717A>G p.P1239= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV99942908; called by muse, mutect2
- FBXO46 | c.234T>C p.A78= | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as COSV100480189; called by muse, mutect2
- FOLR2 | c.27G>A p.L9= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV99995472; called by muse, mutect2
- GBA2 | c.60C>T p.S20= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV65239496; called by muse, mutect2
- GLI1 | c.2622T>C p.P874= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1326011304, COSV57361717; called by muse, mutect2
- GPSM3 | c.222C>T p.S74= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV100900679; called by muse, mutect2
- H3C1 | c.102C>T p.G34= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs753275705, COSV55119423; called by muse, mutect2, varscan2
- H6PD | c.1050G>A p.E350= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV66231001; called by muse, mutect2, varscan2
- HERC2 | c.903C>T p.G301= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1281440750, COSV55323079; called by muse, mutect2, varscan2
- KIAA2026 | c.2787A>G p.T929= | Silent (SNP) | VAF 28/734 reads (4%) | catalogued as COSV101199053; called by muse, mutect2
- KLF1 | c.1050C>T p.R350= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99322422; called by muse, mutect2
- KRT82 | c.276C>T p.I92= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV99233610; called by muse, mutect2
- KRT85 | c.1449T>C p.P483= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as CD100974, COSV99225459; called by mutect2, varscan2
- LRRC23 | c.957A>T p.R319= | Silent (SNP) | VAF 28/748 reads (4%) | catalogued as rs782283515, COSV99145197; called by muse, mutect2
- LRRC7 | c.2583C>T p.L861= (on ENST00000651989 / NM_001370785.2; = p.L828= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 43/283 reads (15%) | catalogued as rs553637103, COSV50454830; called by muse, mutect2, varscan2
- MAGEC3 | c.1710A>G p.E570= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV53580070; called by muse, mutect2
- MCF2L | c.1032G>A p.Q344= (on ENST00000375608; = p.Q312= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV65048857; called by muse, mutect2
- MEIS3 | c.108C>T p.G36= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs1170155241, COSV58983496; called by muse, mutect2
- MUC16 | c.33663G>A p.A11221= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as rs373172082; called by muse, mutect2, varscan2
- MXD3 | c.570C>T p.F190= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs533160184, COSV57463294; called by muse, mutect2, varscan2
- NKRF | c.813A>G p.V271= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV58661539; called by muse, mutect2
- PDE1C | c.42C>T p.C14= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101275540, COSV68809302; called by muse, mutect2
- PRELP | c.219T>C p.C73= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as rs1365100303, COSV58115838; called by muse, mutect2
- PRMT7 | c.1188G>A p.R396= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100266979; called by muse, mutect2
- PTCHD3 | c.1671A>G p.P557= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV101438908; called by muse, mutect2
- RASGRF2 | c.2278C>T p.L760= | Silent (SNP) | VAF 10/283 reads (4%) | catalogued as COSV99429265; called by muse, mutect2
- RING1 | c.117T>A p.P39= | Silent (SNP) | VAF 8/200 reads (4%) | catalogued as COSV100761782; called by muse, mutect2
- RIOK3 | c.174A>G p.E58= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1391656653; called by muse, mutect2
- ROBO2 | c.1152C>T p.S384= | Silent (SNP) | VAF 18/263 reads (7%) | catalogued as rs776288183, COSV100166858; called by muse, mutect2
- RYR1 | c.5466T>A p.G1822= | Silent (SNP) | VAF 11/279 reads (4%) | catalogued as COSV100615763; called by muse, mutect2
- SLC12A8 | c.936C>T p.F312= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100102396; called by muse, mutect2
- SLC27A6 | c.390C>T p.C130= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV52488934; called by muse, mutect2
- SSRP1 | c.1233C>T p.Y411= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs899486390, COSV53479397; called by muse, mutect2
- SYTL5 | c.1179C>T p.S393= | Silent (SNP) | VAF 25/994 reads (3%) | catalogued as rs1408778597, COSV52903033; called by muse, mutect2
- TAGAP | c.1050C>A p.A350= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1387800765; called by muse, mutect2
- TENM2 | c.7242A>G p.G2414= (on ENST00000518659 / NM_001122679.2; = p.G2175= on NM_001080428.3) | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV101318681; called by muse, mutect2
- TFDP1 | c.789C>T p.I263= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs200050514; called by muse, mutect2, varscan2
- TRIM4 | c.1314G>A p.Q438= | Silent (SNP) | VAF 38/1374 reads (3%) | catalogued as COSV100584299; called by muse, mutect2
- TRO | c.888G>A p.R296= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV51501355; called by muse, mutect2
- TSSK4 | c.939G>A p.Q313= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1289955421, COSV55303164; called by muse, mutect2
- TTC7A | c.2415C>T p.A805= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs771372965, COSV55410858, COSV99766681; called by muse, mutect2, varscan2
- TTN | c.3570G>A p.Q1190= (on ENST00000591111; = p.Q1144= on NM_003319.4) | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV100613455; called by muse, mutect2
- UBR2 | c.4233T>C p.I1411= | Silent (SNP) | VAF 18/322 reads (6%) | catalogued as COSV100867447; called by muse, mutect2
- VDAC1 | c.153C>A p.T51= | Silent (SNP) | VAF 10/255 reads (4%) | catalogued as COSV99527238; called by muse, mutect2
- WDR43 | c.1257T>C p.P419= | Silent (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- ZFAND4 | c.1470A>G p.P490= | Silent (SNP) | VAF 15/448 reads (3%) | catalogued as COSV100762980; called by muse, mutect2
- ZNF350 | c.576C>T p.I192= | Silent (SNP) | VAF 28/858 reads (3%) | catalogued as COSV99702542; called by muse, mutect2
- ZNF526 | c.1410G>A p.R470= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as COSV55899234; called by muse, mutect2, varscan2
- ZNF80 | c.534G>A p.R178= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV100352032; called by muse, mutect2
- ZNF835 | c.174C>T p.S58= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV101606321; called by muse, mutect2
- ZSCAN5A | c.753A>G p.R251= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV99570185; called by muse, mutect2
- ATP6V0E1 | chr5:173020750 G>A | 3'Flank (SNP) | VAF 18/404 reads (4%) | catalogued as COSV99439144; called by muse, mutect2
- CACNA1C | c.1481+584C>T | Intron (SNP) | VAF 4/88 reads (5%) | catalogued as rs1376791156, COSV100219066; called by muse, mutect2
- MRPL33 | c.*45G>A | 3'UTR (SNP) | VAF 8/200 reads (4%) | catalogued as COSV99941409; called by muse, mutect2
- PPP1R8 | c.*1133T>G | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52579994; called by muse, mutect2
